Somatic mutation profile of tumor specimen TARGET-15-SJMPAL011911-03A.1 (aliquot TARGET-15-SJMPAL011911-03A.1-01D) from TARGET case TARGET-15-SJMPAL011911, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,731 days).
Specimen TARGET-15-SJMPAL011911-03A.1: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 604b0382-750a-413b-b3e6-f891fb4fce84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL011911-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL011911-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6114244-cf86-48de-b477-49f5c327c18a

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARF | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775019489, COSV57548232, COSV57548286; called by muse, mutect2, varscan2
- CCL8 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1304781245; called by muse, mutect2
- GRIN2B | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV101663122; called by muse, mutect2, varscan2
- NPAP1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs1170974294, COSV61505991; called by muse, mutect2, varscan2
- RUNX1 | c.538_539insCC p.R180Pfs*5 (on ENST00000344691 / NM_001001890.3; = p.R207Pfs*5 on NM_001754.5) | Frame Shift Ins (INS) | VAF 21/37 reads (57%) | catalogued as COSV55880386, COSV99038740; called by mutect2, pindel, varscan2
- THOC6 | c.194G>C p.S65T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.468); catalogued as rs1455090114; called by muse, mutect2, varscan2
- TMPRSS15 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362308542, COSV53043850; called by muse, mutect2, varscan2
- WT1 | c.1096_1099delinsACTTTTTAGGA p.L366Tfs*3 | Nonsense Mutation (INS) | VAF 37/126 reads (29%) | catalogued as COSV60072365; called by pindel, varscan2*
- BRINP2 | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DAGLB | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- PLA2R1 | c.2387G>T p.C796F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEPTIN14 | c.961G>T p.V321L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2
- SLC27A4 | c.471C>A p.N157K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDH17 | c.1521T>C p.H507= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- DNAJB4 | c.423A>T p.G141= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- EFCAB11 | c.126C>T p.D42= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- KCNIP3 | c.549C>A p.T183= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- NSL1 | c.219G>T p.L73= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12258G>T | Intron (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- TPK1 | c.185+15159G>A | Intron (SNP) | VAF 24/69 reads (35%) | catalogued as rs1375349156; called by muse, mutect2, varscan2
